Surgical pathology report (de-identified scan), TCGA case TCGA-GD-A3OS, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GD-A3OS-01A (Primary Tumor).

Final Pathologic Diagnosis:

Urinary bladder, transurethral resection:

Histologic type: Urothelial carcinoma

Variant histology: Transitional cell (85%), sarcomatoid (10%)

and squamous (<5%)

Grade (WHO): High

Tumor configuration: Infiltrative

Microscopic extent of tumor: Tumor invades the muscularis propria

Lymph-vascular invasion: Not identified

Muscularis propria present: Present, involved by tumor

Associated epithelial lesions: No

Additional pathologic findings: Extensive necrosis

Pathologic stage: At least pT2a

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimen is received in a single formalin filled container labeled with the patient's name and additionally labeled "bladder tumor" and consists of a 3.5 x 3 x 0.5 cm aggregate of pink-tan tissue fragments. The specimen is submitted in toto in seven cassettes. Levels are requested.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken:

(Age: Gender:

ICD-0.3

carcinoma, urothelial, NOS 8120/3

Site: bladder, NOS C67.9

fw
2/5/12

Source: NCI Genomic Data Commons file 9358bb8f-0081-45be-866c-5c167454f94b (TCGA-GD-A3OS.FB313E2A-4B08-44FA-A872-00EF40064FB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).